Somatic mutation profile of tumor specimen TARGET-10-PAPFZL-09A (aliquot TARGET-10-PAPFZL-09A-01D) from TARGET case TARGET-10-PAPFZL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (917 days).
Specimen TARGET-10-PAPFZL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8b1572a-4828-42e3-95f2-70c8a7f80415.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPFZL-14A (Bone Marrow Normal), aliquot TARGET-10-PAPFZL-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/063ca577-8903-4327-9b96-0c0f7267f360

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Nonsense Mutation 2, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC93 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200247512, COSV60119161, COSV60122319; called by muse, mutect2, varscan2
- CDH9 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 6/142 reads (4%) | catalogued as COSV50325969, COSV50406227; called by muse, mutect2
- CEP128 | c.2418G>A p.M806I | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.542); catalogued as COSV55387757; called by muse, mutect2
- EZH2 | c.1727C>A p.A576D (on ENST00000460911 / NM_001203247.2; = p.A581D on NM_004456.5) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV57459141; called by muse, mutect2, varscan2
- SLC22A6 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64560322; called by muse, mutect2
- KIAA2012 | c.1702G>T p.E568* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- SLC16A2 | c.959C>A p.T320N | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.246); called by muse, mutect2
- SLC18B1 | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TFAP2A | c.988C>A p.P330T (on ENST00000482890; = p.P322T on NM_001032280.3) | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); called by muse, mutect2
- CCDC85A | c.1026C>T p.H342= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs770275487, COSV68154262; called by mutect2, varscan2
- SMUG1 | c.286-55C>T | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as rs1272975089; called by muse, mutect2
